Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5095, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5095-01A (Primary Tumor).

RENAL DIAGNOSIS

KIDNEY, RIGHT, RADICAL NEPHRECTOMY -

- A. RENAL CELL CARCINOMA, CLEAR CELL TYPE.
- B. FUHRMAN NUCLEAR GRADE IS 3 of 4.
- C. THE GREATEST DIAMETER OF THE NEOPLASM IS 10.2 cm.
- D. THE NEOPLASM EXTENDS INTO THE RENAL SINUS FAT AND THROUGH THE RENAL CAPSULE.
- E. NO EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- F. ALL SURGICAL MARGINS ARE FREE OF THE NEOPLASM.
- G. NON-NEOPLASTIC KIDNEY SHOWS CHRONIC INTERSTITIAL INFLAMMATION AND GLOMERULOSCLEROSIS.
- H. TNM STAGE: pT3a NX MX.

Source: NCI Genomic Data Commons file fc028408-eebe-4c45-93a7-d05c4daa8f0d (TCGA-B0-5095.5AE8298D-57AD-4F4C-A11D-431E4023A236.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).